Somatic mutation profile of tumor specimen ALCH-B204-TTP1-A (aliquot ALCH-B204-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B204, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.3 years (20,571 days).
Specimen ALCH-B204-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7106858-1d5d-4c6e-a727-d53f36423345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B204-NB1-A (Blood Derived Normal), aliquot ALCH-B204-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a680b05-bdbe-4b66-a796-b5470cf4e2d4

The open-access MAF lists 940 somatic variants for this specimen: 632 protein-altering or splice-affecting, 214 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 548, Silent 214, Nonsense Mutation 51, Intron 48, Splice Site 17, RNA 13, 5'UTR 11, Frame Shift Del 9, 3'Flank 9, 5'Flank 8, Splice Region 6, 3'UTR 5.

Variants (750 of 940; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 185/767 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 111/816 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 60/575 reads (10%) | catalogued as rs761213176, COSV70025531; called by muse, mutect2, varscan2
- ACTL9 | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV61006433; called by muse, mutect2, varscan2
- ADAM21 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs765502625, COSV50788604; called by muse, mutect2
- ADAMTS16 | c.2655C>A p.C885* | Nonsense Mutation (SNP) | VAF 41/423 reads (10%) | catalogued as rs749886441, COSV57003255; called by muse, mutect2, varscan2
- ADAMTS20 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67139241; called by muse, mutect2
- ADCY2 | c.1784C>A p.T595K | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV57878323; called by muse, mutect2, varscan2
- ADCY8 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 149/1137 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53913774; called by muse, varscan2
- ADGRG4 | c.311T>A p.L104* | Nonsense Mutation (SNP) | VAF 58/455 reads (13%) | catalogued as COSV54965650; called by muse, mutect2, varscan2
- ADGRL3 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 59/536 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1024375520, COSV101547190; called by muse, mutect2, varscan2
- AGAP1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 59/522 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs745570362; called by muse, mutect2, varscan2
- AKAP6 | c.5415G>A p.W1805* | Nonsense Mutation (SNP) | VAF 60/496 reads (12%) | catalogued as rs866029994; called by muse, mutect2, varscan2
- AKAP9 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 37/406 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV100662885; called by muse, mutect2
- ALKBH1 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 36/618 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53659856; called by muse, mutect2
- ALKBH8 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1235041548; called by muse, mutect2, varscan2
- ALOX5 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs778612367, COSV65552020; called by muse, varscan2
- ANKRD62 | c.2196G>T p.L732F | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58409623; called by muse, mutect2
- ASIC5 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101611178, COSV73332580; called by muse, mutect2
- ATCAY | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56656922; called by muse, mutect2, varscan2
- ATRX | c.4882C>A p.L1628I | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64886413; called by muse, mutect2
- BCAN | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs754590703; called by muse, mutect2, varscan2
- BIN2 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 44/563 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.195); catalogued as rs146877980, COSV57204685, COSV99909651; called by muse, mutect2
- BMPER | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV51821897; called by muse, mutect2, varscan2
- BRD3 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.4); catalogued as rs1464507474, COSV57705687; called by muse, mutect2
- CACNA1F | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 77/658 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV59906388; called by muse, mutect2, varscan2
- CALB1 | c.321G>T p.W107C | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55368332; called by muse, mutect2, varscan2
- CD5L | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs879069186, COSV100941033, COSV63821041; called by muse, mutect2
- CDC42EP4 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs771224003, COSV100231804; called by muse, mutect2, varscan2
- CHD7 | c.8532G>T p.E2844D | Missense Mutation (SNP) | VAF 188/1283 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV71110088; called by muse, mutect2, varscan2
- CHRM3 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99699902; called by muse, mutect2
- CHRNA1 | c.525C>G p.I175M (on ENST00000261007 / NM_001039523.3; = p.I150M on NM_000079.4) | Missense Mutation (SNP) | VAF 33/582 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.718); catalogued as rs200163630; ClinVar: uncertain significance; called by muse, mutect2
- CHRNA7 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV60972618; called by muse, mutect2, varscan2
- CLTCL1 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1198938654; called by muse, mutect2, varscan2
- COL11A1 | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 54/788 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368422725; ClinVar: uncertain significance; called by muse, mutect2
- COL19A1 | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs199945062, COSV59571622; called by muse, mutect2
- COL20A1 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1186284624; called by muse, mutect2
- COL22A1 | c.3741A>T p.R1247S | Missense Mutation (SNP) | VAF 21/430 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV100277658; called by muse, mutect2
- CRHR2 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | catalogued as rs1375903912, COSV59264514; called by muse, mutect2
- CRTAC1 | c.1971C>A p.C657* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as rs773387702, COSV54001784, COSV54008445; called by muse, mutect2
- CSMD3 | c.9315G>T p.R3105S (on ENST00000297405 / NM_001363185.1; = p.R2936S on NM_052900.3) | Missense Mutation (SNP) | VAF 95/761 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.186); catalogued as COSV99839580; called by muse, mutect2, varscan2
- CSMD3 | c.9020C>A p.S3007Y (on ENST00000297405 / NM_001363185.1; = p.S2838Y on NM_052900.3) | Missense Mutation (SNP) | VAF 127/898 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV99033802; called by muse, mutect2, varscan2
- CSMD3 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 67/509 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV52240381; called by muse, mutect2, varscan2
- CTNND2 | c.2402A>G p.K801R | Missense Mutation (SNP) | VAF 100/588 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV58933945; called by muse, mutect2, varscan2
- CTNND2 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 15/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58872161; called by muse, mutect2
- CUX2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs748957015, COSV55650390; called by muse, mutect2, varscan2
- CYP2C9 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 66/716 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53246556, COSV53248796; called by muse, mutect2
- DCAF4L2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100151310; called by muse, mutect2, varscan2
- DCAF4L2 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 65/547 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.269); catalogued as COSV60478173; called by muse, mutect2, varscan2
- DGKB | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99338209; called by muse, mutect2
- DHRS2 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 74/564 reads (13%) | catalogued as COSV51632644; called by muse, mutect2, varscan2
- DIS3L2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 63/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018058365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLX5 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 20/570 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV56034636; called by muse, mutect2
- DSEL | c.1426G>T p.G476* | Nonsense Mutation (SNP) | VAF 35/287 reads (12%) | catalogued as COSV100025243; called by muse, mutect2, varscan2
- DSG4 | c.2512C>A p.P838T | Missense Mutation (SNP) | VAF 40/611 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57397489; called by muse, mutect2
- DUS4L-BCAP29 | c.1070T>A p.L357* | Nonsense Mutation (SNP) | VAF 19/598 reads (3%) | catalogued as COSV50051437; called by muse, mutect2
- DUXA | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 138/641 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV73729737; called by muse, mutect2, varscan2
- EP400 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1284097784, COSV57787756; called by muse, mutect2
- EP400 | c.4477G>T p.A1493S | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100201788; called by muse, mutect2, varscan2
- EPHB2 | c.2234G>T p.R745L (on ENST00000400191 / NM_001309193.2; = p.R746L on NM_004442.7) | Missense Mutation (SNP) | VAF 21/622 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65867538; called by muse, mutect2
- EPHB2 | c.2467G>T p.G823W (on ENST00000400191 / NM_001309193.2; = p.G824W on NM_004442.7) | Missense Mutation (SNP) | VAF 34/564 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006847; called by muse, mutect2
- EXTL2 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 34/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473166; called by muse, mutect2
- EYA4 | c.1006C>T p.Q336* (on ENST00000531901 / NM_001301013.1; = p.Q330* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 75/666 reads (11%) | catalogued as COSV62060453; called by muse, mutect2, varscan2
- EYS | c.2354C>A p.T785N | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65529313; called by muse, mutect2
- FAM47A | c.1634C>A p.P545Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.238); catalogued as COSV60496012, COSV60498636; called by muse, varscan2
- FAT4 | c.5446G>T p.A1816S | Missense Mutation (SNP) | VAF 82/623 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58673765; called by muse, mutect2, varscan2
- FCGR2A | c.383C>A p.T128N (on ENST00000271450 / NM_001136219.3; = p.T127N on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780937135; called by muse, mutect2
- FLI1 | c.1245C>G p.F415L | Missense Mutation (SNP) | VAF 164/661 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55642782; called by muse, mutect2, varscan2
- FMN2 | c.4141G>T p.D1381Y | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60439532; called by muse, mutect2, varscan2
- FOXM1 | c.2102A>G p.K701R | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs770372738; called by muse, mutect2
- FSIP2 | c.2560C>A p.Q854K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs1394392350; called by muse, mutect2
- GALNT13 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 29/662 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.776); catalogued as COSV101223014; called by muse, mutect2
- GALNT17 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV61155523; called by muse, mutect2
- GALNT9 | c.477C>G p.F159L | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV61099085; called by muse, mutect2
- GALNT9 | c.476T>A p.F159Y | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.668); catalogued as rs1259099561; called by muse, mutect2
- GLI3 | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 40/623 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230067; called by muse, mutect2
- GLT1D1 | c.813G>T p.R271S (on ENST00000442111 / NM_001366889.1; = p.R191S on NM_144669.3) | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55885045; called by muse, mutect2
- GPR141 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731234, COSV57733505; called by muse, mutect2, varscan2
- GPR149 | c.1527A>T p.E509D | Missense Mutation (SNP) | VAF 52/632 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101078415; called by muse, mutect2
- GPR26 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV52932668; called by muse, mutect2, varscan2
- GRIN2A | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58022081, COSV58032220; called by muse, mutect2, varscan2
- GRM6 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1340110862; called by muse, mutect2, varscan2
- GSDMA | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 54/514 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV52856978; called by muse, mutect2, varscan2
- HEATR6 | c.3388C>G p.Q1130E | Missense Mutation (SNP) | VAF 91/481 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1568598737; called by muse, mutect2, varscan2
- HECW2 | c.3989G>T p.R1330L | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99649323; called by muse, mutect2
- HES4 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774882183; called by muse, mutect2
- HK3 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.385); catalogued as COSV99459423; called by muse, mutect2, varscan2
- HMCN1 | c.3449G>C p.C1150S | Missense Mutation (SNP) | VAF 64/1510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1558125327; called by muse, mutect2
- HS3ST1 | c.306G>C p.W102C | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560230864, COSV50026602; called by muse, mutect2, varscan2
- IGKV1-8 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 107/825 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs779655759; called by muse, mutect2, varscan2
- IL1R1 | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52108208; called by muse, mutect2, varscan2
- INHBA | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV54221936; called by muse, mutect2
- INMT | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as rs774018864, COSV99184986; called by muse, mutect2, varscan2
- INSIG1 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1245965554; called by muse, mutect2
- JPH4 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV100689197; called by muse, mutect2
- KCNA4 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60255178; called by muse, mutect2
- KCNH8 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 109/651 reads (17%) | catalogued as COSV60459063, COSV60464216; called by muse, mutect2, varscan2
- KCNV1 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 65/601 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV52085240; called by muse, mutect2, varscan2
- KIF2B | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 105/701 reads (15%) | catalogued as rs1424466838, COSV52129086; called by muse, mutect2, varscan2
- KIRREL1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1386379566; called by muse, mutect2, varscan2
- KLHL1 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 65/477 reads (14%) | catalogued as COSV64771429; called by muse, mutect2, varscan2
- LAMB4 | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 50/625 reads (8%) | catalogued as COSV52718044; called by muse, mutect2
- LILRA2 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 76/749 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV52189795; called by muse, mutect2
- LIPI | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs865932587; called by muse, mutect2
- LMNA | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 108/787 reads (14%) | catalogued as CM033632; called by muse, mutect2, varscan2
- LRP1B | c.13299C>A p.S4433R | Missense Mutation (SNP) | VAF 34/802 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs1171270062; called by muse, mutect2
- LRP1B | c.8645C>A p.P2882Q | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs764441931; called by muse, mutect2, varscan2
- LRP1B | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 56/639 reads (9%) | catalogued as COSV67227027; called by muse, mutect2
- LRRC14B | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779597045, COSV52047185; called by muse, mutect2, varscan2
- LRRIQ1 | c.4282G>C p.D1428H | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs780129357, COSV67834641, COSV67834972; called by muse, mutect2
- LSS | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 21/396 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as rs762530682; called by muse, mutect2
- LYPLAL1 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65106822; called by muse, mutect2
- MAN1A1 | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1362938892; called by muse, mutect2, varscan2
- MAP3K1 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 97/831 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV68122792; called by muse, mutect2, varscan2
- MAPK4 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68542178; called by muse, mutect2
- MELTF | c.1515C>A p.D505E | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.392); catalogued as rs570845591; called by muse, varscan2
- MET | c.1527G>A p.K509= | Splice Region (SNP) | VAF 56/818 reads (7%) | catalogued as COSV59256463; called by muse, mutect2
- MOGAT3 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs1364089678; called by muse, mutect2
- MSI2 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs1466564664; called by muse, mutect2, varscan2
- MUC16 | c.20636C>A p.A6879D | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs750114807, COSV67492136; called by muse, mutect2, varscan2
- MUC16 | c.19665G>A p.M6555I | Missense Mutation (SNP) | VAF 71/474 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.043); catalogued as rs758572548, COSV67481274; called by muse, mutect2, varscan2
- MXRA5 | c.2938C>G p.P980A | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54256105; called by muse, mutect2
- MYLK | c.4520G>A p.R1507Q | Missense Mutation (SNP) | VAF 46/823 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs574296889, COSV60607332; ClinVar: uncertain significance; called by muse, mutect2
- NAP1L3 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 25/213 reads (12%) | catalogued as COSV100220346; called by muse, mutect2, varscan2
- NBAS | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 41/550 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as CD157052; called by muse, mutect2
- NCF1 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 100/1364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194284; called by muse, mutect2
- NPFFR2 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100440510; called by muse, mutect2, varscan2
- NRG3 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778668743; called by muse, mutect2, varscan2
- NUBP1 | c.764T>C p.M255T | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1369925368; called by muse, mutect2
- OBSCN | c.9176G>T p.G3059V | Missense Mutation (SNP) | VAF 109/408 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.873); catalogued as rs779073171; called by muse, mutect2, varscan2
- OBSCN | c.18035G>A p.R6012Q | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs759113111; called by muse, mutect2
- OR14C36 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58602136, COSV58603027; called by muse, varscan2
- OR1C1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV68715848; called by muse, mutect2, varscan2
- OR1C1 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779917177; called by muse, mutect2
- OR2A5 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs1439381330, COSV68738619, COSV68738891; called by muse, mutect2, varscan2
- OR2B11 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV59509331; called by muse, mutect2, varscan2
- OR2C3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV63576022; called by muse, mutect2
- OR2M4 | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as rs1450977935, COSV100141241; called by muse, mutect2, varscan2
- OR52K2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 5/93 reads (5%) | catalogued as COSV57835059; called by muse, mutect2
- OR7G2 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV59687825; called by muse, mutect2
- OR8H3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV100539105; called by muse, mutect2, varscan2
- OR9G4 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.07); catalogued as rs747446138, COSV57248340; called by muse, mutect2
- PAMR1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 64/612 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552454; called by muse, mutect2, varscan2
- PAPPA2 | c.3290del p.G1097Efs*10 | Frame Shift Del (DEL) | VAF 51/587 reads (9%) | catalogued as COSV62812411; called by mutect2, pindel
- PARD6B | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 73/575 reads (13%) | catalogued as COSV65404563, COSV65404745; called by muse, mutect2, varscan2
- PAX4 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 37/911 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV58387486; called by muse, mutect2
- PCDHA2 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 59/489 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.697); catalogued as COSV65365869; called by muse, mutect2, varscan2
- PCDHA4 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 78/643 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63542624, COSV63544930; called by muse, mutect2, varscan2
- PCDHA4 | c.734C>G p.T245S | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100793706; called by muse, mutect2
- PCDHA7 | c.1919C>A p.T640K | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.258); catalogued as COSV65342627; called by muse, mutect2, varscan2
- PCDHA9 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 138/886 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV65333097; called by muse, varscan2
- PCDHB10 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as rs201669614, COSV53375236; called by muse, mutect2, varscan2
- PCDHB10 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 112/733 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53382624; called by muse, mutect2, varscan2
- PCDHGA4 | c.1444A>T p.T482S | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV53947091; called by muse, mutect2
- PCDHGB2 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs529112132, COSV99538104; called by muse, mutect2, varscan2
- PCDHGB2 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 112/752 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs750712376; called by muse, mutect2, varscan2
- PCDHGB4 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 71/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99528624; called by muse, mutect2, varscan2
- PCLO | c.10063G>T p.A3355S | Missense Mutation (SNP) | VAF 126/706 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs1387464014; called by muse, mutect2, varscan2
- PIP5K1B | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99599544; called by muse, mutect2, varscan2
- POTEF | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 62/579 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV62543483; called by muse, mutect2, varscan2
- PRRX1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs1464419142, COSV53416880, COSV53417805, COSV99509573; called by muse, mutect2, varscan2
- PRSS55 | c.41C>A p.T14K | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs201824405, COSV100153591, COSV100153630; called by muse, varscan2
- PTPRR | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 59/493 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs895859673; called by muse, mutect2, varscan2
- REG1A | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.866); catalogued as rs267599471, COSV52069911; called by muse, mutect2, varscan2
- RELN | c.9154G>T p.E3052* | Nonsense Mutation (SNP) | VAF 34/1038 reads (3%) | catalogued as COSV59014672; called by muse, mutect2
- RELN | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as rs757218424; called by muse, mutect2, varscan2
- RGPD4 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 47/670 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100736309; called by muse, mutect2, varscan2
- RNF213 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 84/617 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV100173834; called by muse, mutect2, varscan2
- RP1L1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 71/535 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.413); catalogued as rs1329261184, COSV66759832; called by muse, mutect2, varscan2
- RPRD2 | c.1211C>A p.T404K | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV64818986; called by muse, mutect2
- SDE2 | c.1054del p.E352Kfs*6 | Frame Shift Del (DEL) | VAF 79/443 reads (18%) | catalogued as rs753034351; called by mutect2, pindel, varscan2
- SEC24B | c.2126+1G>T p.X709_splice | Splice Site (SNP) | VAF 31/322 reads (10%) | catalogued as COSV54505775; called by muse, mutect2
- SH3RF3 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 178/644 reads (28%) | catalogued as COSV100512804, COSV58684112; called by muse, mutect2, varscan2
- SLC14A1 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 100/786 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs959314162; called by muse, mutect2, varscan2
- SLC17A8 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 111/804 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV60123274; called by muse, mutect2, varscan2
- SLFN5 | c.862G>C p.A288P | Missense Mutation (SNP) | VAF 63/570 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV55480418, COSV55482313; called by muse, mutect2, varscan2
- SLITRK4 | c.889C>A p.H297N | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99052644; called by muse, mutect2
- SMPD4 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1341212470; called by muse, mutect2
- SPTA1 | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 52/1194 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs367992735; called by muse, mutect2
- SPTA1 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 233/1147 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100934087; called by muse, mutect2, varscan2
- STAC | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 56/220 reads (25%) | catalogued as COSV56212162; called by muse, varscan2
- STK11 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV104400710; called by muse, mutect2, varscan2
- STX2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749093431, COSV55433329; called by muse, mutect2, varscan2
- TAS2R16 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV50797488; called by muse, mutect2, varscan2
- TBX22 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 62/646 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074594; called by muse, mutect2
- TCHHL1 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs1485654568; called by muse, mutect2
- TDRD3 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs768028055; called by muse, mutect2, varscan2
- TENM2 | c.1787G>T p.G596V (on ENST00000518659 / NM_001122679.2; = p.G364V on NM_001080428.3) | Missense Mutation (SNP) | VAF 52/504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69131848; called by muse, mutect2
- TENM4 | c.174C>A p.S58R | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV53613508; called by muse, mutect2, varscan2
- TLE1 | c.840del p.K281Rfs*19 | Frame Shift Del (DEL) | VAF 37/353 reads (10%) | catalogued as COSV100916353; called by mutect2, pindel, varscan2
- TRIM47 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV54668952; called by muse, mutect2, varscan2
- TRIM58 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV63569072; called by muse, mutect2, varscan2
- TSHZ2 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV61587862; called by muse, mutect2, varscan2
- TSHZ2 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.238); catalogued as rs777134610, COSV61590230; called by muse, mutect2
- TSHZ3 | c.2409G>T p.L803F | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as COSV53683222; called by muse, varscan2
- TTN | c.82217A>G p.K27406R (on ENST00000591111; = p.K19982R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/316 reads (8%) | PolyPhen benign (0.029); catalogued as COSV60217175; called by muse, mutect2
- TUBAL3 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781957821; called by muse, mutect2
- UBR4 | c.7017G>T p.E2339D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV64394747; called by muse, mutect2
- UFL1 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751367115; called by muse, mutect2, varscan2
- UGT1A5 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 68/562 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.728); catalogued as COSV59380995; called by muse, mutect2, varscan2
- VCAM1 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 44/730 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99658585; called by muse, mutect2
- VCP | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); catalogued as COSV62721194; called by muse, mutect2
- VOPP1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 53/475 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs775489820; called by muse, mutect2, varscan2
- VWF | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV54621841; called by muse, mutect2, varscan2
- WDFY4 | c.3025C>A p.R1009S | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57438260; called by muse, mutect2, varscan2
- WNT10B | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 62/450 reads (14%) | catalogued as COSV99975796; called by muse, varscan2
- XIRP2 | c.5256G>T p.R1752S (on ENST00000628543; = p.R1927S on NM_152381.6) | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV54718552, COSV99744756; called by muse, mutect2
- XIRP2 | c.6446G>T p.G2149V (on ENST00000628543; = p.G2324V on NM_152381.6) | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs776896507; called by muse, mutect2, varscan2
- ZBTB1 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 41/444 reads (9%) | catalogued as COSV62438934; called by muse, mutect2
- ZCCHC13 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs1165617310; called by muse, mutect2
- ZFHX2 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 68/543 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs557418110; called by muse, mutect2, varscan2
- ZFHX4 | c.6472C>T p.Q2158* | Nonsense Mutation (SNP) | VAF 48/481 reads (10%) | catalogued as COSV51490053; called by muse, mutect2
- ZFR2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV53602564; called by muse, mutect2
- ABCB10 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD16B | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABI3 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC013477.1 | c.2561A>G p.Q854R | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); called by muse, varscan2
- ACSBG1 | c.1017del p.W339* | Frame Shift Del (DEL) | VAF 37/310 reads (12%) | called by mutect2, pindel, varscan2
- ACSL6 | c.637G>A p.V213M (on ENST00000379240; = p.V238M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2
- ADAMTS12 | c.2410C>A p.P804T | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS12 | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 175/1017 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.4580G>T p.S1527I | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4329G>T p.L1443F | Missense Mutation (SNP) | VAF 80/423 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ADCK1 | c.94A>T p.N32Y | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ADCY2 | c.3206G>C p.G1069A | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRL3 | c.4543C>G p.P1515A (on ENST00000506720 / NM_001322402.2; = p.P1404A on NM_015236.6) | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALDH6A1 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 123/770 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMER1 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANK2 | c.4012G>T p.D1338Y | Missense Mutation (SNP) | VAF 80/1047 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.7774G>C p.V2592L | Missense Mutation (SNP) | VAF 72/715 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ANK2 | c.8722G>T p.V2908F | Missense Mutation (SNP) | VAF 132/1413 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); called by muse, mutect2
- ANKRD26 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 44/574 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2
- ANKRD26 | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 47/587 reads (8%) | called by muse, mutect2
- ANKRD30B | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ANKRD36C | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- ANKRD50 | c.4108C>G p.Q1370E | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ANO4 | c.2194C>A p.L732I (on ENST00000392977 / NM_001286615.2; = p.L697I on NM_178826.4) | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP33 | c.1943-5C>G | Splice Region (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 135/548 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARRDC4 | c.1142G>C p.C381S | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASGR2 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ASL | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2
- ASL | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 39/647 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ASMT | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ATP6V0A4 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 46/724 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.035); called by muse, mutect2
- ATP8B4 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ATR | c.4279A>T p.I1427F | Missense Mutation (SNP) | VAF 27/533 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- B3GAT2 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, varscan2
- BARX1 | c.601-1G>A p.X201_splice | Splice Site (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2
- BAZ1A | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 96/579 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BAZ2A | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BMP5 | c.566A>T p.H189L | Missense Mutation (SNP) | VAF 136/533 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BMPR1B | c.723G>C p.W241C | Missense Mutation (SNP) | VAF 59/487 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRMS1 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- C18orf63 | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- C4orf54 | c.1331C>A p.T444K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- C4orf54 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C6 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 134/857 reads (16%) | called by muse, mutect2, varscan2
- C8orf34 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2
- C8orf48 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- C9orf135 | c.449+3T>C | Splice Region (SNP) | VAF 56/548 reads (10%) | called by muse, mutect2
- CA10 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CACNA1F | c.5004G>T p.Q1668H | Missense Mutation (SNP) | VAF 75/722 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CACNA1F | c.3259G>T p.G1087C | Missense Mutation (SNP) | VAF 58/569 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1H | c.3094G>T p.D1032Y | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CACNA2D1 | c.3002G>A p.R1001K (on ENST00000356253 / NM_001366867.1; = p.R989K on NM_000722.4) | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- CACNG6 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.092); called by muse, mutect2
- CADM2 | c.176C>T p.P59L (on ENST00000407528 / NM_001167674.2; = p.P61L on NM_153184.4) | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.19345G>T p.G6449W | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2
- CCDC74B | c.544+1G>T p.X182_splice | Splice Site (SNP) | VAF 39/368 reads (11%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 116/421 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDH17 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 100/726 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CDH8 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CDSN | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 148/690 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP112 | c.2571G>T p.K857N (on ENST00000392769 / NM_001353127.1; = p.K113N on NM_001037325.3) | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CES3 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHL1 | c.1840C>A p.P614T (on ENST00000397491 / NM_001253387.1; = p.P630T on NM_006614.4) | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- CHN1 | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CKAP2L | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 85/374 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLSTN2 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMYA5 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CNTN1 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 81/877 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CNTNAP3 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 102/740 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- COL11A1 | c.4472C>T p.P1491L | Missense Mutation (SNP) | VAF 74/944 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- COL11A1 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 33/570 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- COL19A1 | c.3278G>C p.S1093T | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- COL21A1 | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 64/810 reads (8%) | called by muse, mutect2
- COL22A1 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL24A1 | c.2005-1G>T p.X669_splice | Splice Site (SNP) | VAF 33/365 reads (9%) | called by muse, mutect2
- COL3A1 | c.3307G>T p.A1103S | Missense Mutation (SNP) | VAF 58/519 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- COL5A1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 70/860 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPN2 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 82/495 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CPT1C | c.1510C>A p.H504N | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRB1 | c.4080G>T p.L1360F | Missense Mutation (SNP) | VAF 69/1470 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CROCC | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.023); called by muse, mutect2
- CRYGC | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- CSRNP3 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.79); called by muse, mutect2
- CTNNA1 | c.63G>T p.R21S | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CTNNA2 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- CTNNAL1 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CYP2E1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DBR1 | c.807A>G p.I269M | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2
- DCT | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DEPDC5 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DIP2C | c.3421G>T p.V1141L | Missense Mutation (SNP) | VAF 51/497 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- DOK6 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 44/515 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- DOP1B | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- DSC3 | c.2236-1G>A p.X746_splice | Splice Site (SNP) | VAF 18/556 reads (3%) | called by muse, mutect2
- DSPP | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); called by muse, varscan2
- DTNA | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 21/487 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DZIP1 | c.1311G>C p.Q437H | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- EFTUD2 | c.350+1G>T p.X117_splice | Splice Site (SNP) | VAF 58/273 reads (21%) | called by muse, mutect2, varscan2
- EHBP1 | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELFN1 | c.1964A>T p.E655V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2
- ELP4 | c.1087G>T p.D363Y (on ENST00000350638; = p.D362Y on NM_019040.5) | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EMC2 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 103/665 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EML6 | c.1933-1G>T p.X645_splice | Splice Site (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- EML6 | c.2651C>A p.T884N | Missense Mutation (SNP) | VAF 42/667 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ENGASE | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- EPHB2 | c.2468G>T p.G823V (on ENST00000400191 / NM_001309193.2; = p.G824V on NM_004442.7) | Missense Mutation (SNP) | VAF 34/559 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXO1 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 156/536 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM131B | c.219del p.K73Nfs*13 | Frame Shift Del (DEL) | VAF 48/478 reads (10%) | called by mutect2, pindel, varscan2
- FAM214B | c.1052A>T p.N351I | Missense Mutation (SNP) | VAF 76/955 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- FAM47B | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAM71B | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- FAM71B | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAT2 | c.4472C>A p.P1491Q | Missense Mutation (SNP) | VAF 120/852 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FAT3 | c.13314G>T p.Q4438H | Missense Mutation (SNP) | VAF 70/565 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- FBN2 | c.7921C>A p.Q2641K | Missense Mutation (SNP) | VAF 70/664 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- FBXW7 | c.1360A>T p.I454L (on ENST00000281708 / NM_001349798.2; = p.I374L on NM_018315.5) | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FETUB | c.666C>A p.S222R | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- FGG | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- FGG | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FMN2 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN2 | c.933A>C p.Q311H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO3 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 66/440 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FUBP3 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 44/451 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2
- FUOM | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- GBX2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 23/278 reads (8%) | called by muse, mutect2
- GDF2 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GHR | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- GLI2 | c.2015G>T p.G672V (on ENST00000361492 / NM_001374353.1; = p.G689V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI2 | c.2674G>T p.E892* (on ENST00000361492 / NM_001374353.1; = p.E909* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/276 reads (7%) | called by muse, mutect2
- GLI2 | c.3280G>A p.V1094M (on ENST00000361492 / NM_001374353.1; = p.V1111M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/689 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); called by muse, mutect2
- GOLGA8T | c.758A>T p.Q253L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by mutect2, varscan2
- GOLGB1 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); called by muse, mutect2
- GOLGB1 | c.638A>C p.Q213P | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GP2 | c.1123T>A p.S375T (on ENST00000381362 / NM_001007240.3; = p.S372T on NM_001502.4) | Missense Mutation (SNP) | VAF 52/498 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GPNMB | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.293); called by muse, mutect2
- GPRIN1 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN3 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- GSDMC | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- GUCY2F | c.3039G>T p.M1013I | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GUCY2F | c.3038T>A p.M1013K | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GYS2 | c.1969A>T p.S657C | Missense Mutation (SNP) | VAF 59/583 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HCLS1 | c.158+5G>T | Splice Region (SNP) | VAF 44/195 reads (23%) | called by muse, mutect2, varscan2
- HDAC9 | c.2363C>A p.T788K | Missense Mutation (SNP) | VAF 30/672 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- HEPH | c.3168G>T p.M1056I (on ENST00000343002; = p.M789I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGF | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 30/845 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLX | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- HMCN2 | c.14795C>T p.T4932I | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCS2 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 123/1054 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- HMX1 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXC9 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HTR1F | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HUNK | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 52/502 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- HUWE1 | c.5702G>T p.R1901L | Missense Mutation (SNP) | VAF 26/585 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- HYAL4 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- IFRD1 | c.925A>C p.M309L | Missense Mutation (SNP) | VAF 228/976 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV1-36 | c.213T>A p.D71E | Missense Mutation (SNP) | VAF 35/718 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.102); called by muse, mutect2
- IGSF9B | c.2042G>T p.W681L | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.079); called by muse, mutect2
- IL26 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL26 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL2RA | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 73/693 reads (11%) | called by muse, mutect2, varscan2
- INSL3 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 84/762 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- IRF8 | c.1009A>C p.S337R | Missense Mutation (SNP) | VAF 78/915 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ISL2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ISLR2 | c.60C>A p.C20* | Nonsense Mutation (SNP) | VAF 30/164 reads (18%) | called by muse, mutect2, varscan2
- ITGA2 | c.2602G>T p.A868S | Missense Mutation (SNP) | VAF 152/987 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ITGA8 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 99/722 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA8 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAE | c.1185C>A p.D395E | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGB8 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ITLN2 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 67/617 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JAK3 | c.2432G>T p.C811F | Missense Mutation (SNP) | VAF 55/669 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2
- KATNIP | c.4615G>T p.G1539C | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNC2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KCTD8 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2012 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- KIR3DL2 | c.330C>G p.S110R | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KLHL29 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 26/463 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- KPNA6 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- KRT4 | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT40 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- L3MBTL1 | c.1826-1G>T p.X609_splice (on ENST00000418998 / NM_001377303.1; = p.X519_splice on NM_015478.7) | Splice Site (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- LAMB3 | c.2190G>T p.Q730H | Missense Mutation (SNP) | VAF 147/1027 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LDB2 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2
- LHCGR | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LMX1A | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- LRFN3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LRP1B | c.7304C>G p.T2435R | Missense Mutation (SNP) | VAF 78/702 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRP2 | c.11351G>T p.C3784F | Missense Mutation (SNP) | VAF 94/1027 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC52 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2
- LRRC53 | c.167T>A p.L56* | Nonsense Mutation (SNP) | VAF 34/398 reads (9%) | called by muse, mutect2
- LRRTM1 | c.1274T>A p.I425N | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LRTM2 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.446); called by muse, mutect2
- LTBP1 | c.3401A>T p.Q1134L (on ENST00000404816 / NM_206943.4; = p.Q808L on NM_000627.4) | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- LTN1 | c.3698A>T p.K1233I | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- MAGEA11 | c.668A>T p.H223L | Missense Mutation (SNP) | VAF 47/561 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- MAGEB10 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 46/644 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB18 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MAGEE1 | c.2051C>A p.P684Q | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2
- MAP3K7 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MARCO | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MDH1B | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 78/870 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2
- MGA | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 66/312 reads (21%) | called by muse, mutect2, varscan2
- MGAM2 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.135); called by muse, mutect2
- MOSPD3 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 25/571 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2
- MPV17L | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2
- MRC2 | c.1927A>T p.I643F | Missense Mutation (SNP) | VAF 81/358 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MROH9 | c.1867G>T p.G623C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSC-AS1 | n.342-3C>A | Splice Region (SNP) | VAF 58/459 reads (13%) | called by muse, mutect2, varscan2
- MTHFSD | c.820A>T p.S274C (on ENST00000360900 / NM_001159377.2; = p.S273C on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MUC6 | c.1707del p.A570Lfs*11 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | called by mutect2, pindel, varscan2
- MXRA5 | c.7784A>T p.H2595L | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2
- MXRA5 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MXRA5 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2
- MYBPH | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 113/689 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.1556C>G p.A519G | Missense Mutation (SNP) | VAF 190/1012 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MYO15B | c.5825A>T p.D1942V | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- MYPN | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 107/973 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NADSYN1 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- NCKAP1 | c.893A>T p.D298V | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NCS1 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NDST3 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2
- NDST3 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- NETO1 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NGEF | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP11 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL4 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 78/668 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- NSD2 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP155 | c.3139G>T p.D1047Y (on ENST00000231498 / NM_153485.3; = p.D988Y on NM_004298.4) | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OBSCN | c.15227A>T p.Q5076L | Missense Mutation (SNP) | VAF 49/699 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- OGT | c.1423-1G>T p.X475_splice | Splice Site (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- OLFML2B | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 158/806 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR10D3 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 118/371 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- OR10P1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 74/572 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR10T2 | c.355A>T p.M119L | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- OR12D3 | c.818T>A p.M273K | Missense Mutation (SNP) | VAF 141/578 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OR14I1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1J1 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.261); called by muse, mutect2
- OR2L2 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR2M2 | c.806C>G p.T269R | Missense Mutation (SNP) | VAF 53/1207 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); called by muse, mutect2
- OR2T2 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 90/1894 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR4K5 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 32/853 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- OR51A4 | c.140T>A p.I47N | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- OR51I2 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR52E6 | c.385T>A p.C129S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- OR56A5 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- OR5B12 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); called by muse, mutect2
- OR6K3 | c.806G>A p.S269N (on ENST00000368146; = p.S253N on NM_001005327.2) | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2
- OR6P1 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 328/1400 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- OR7C1 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR9I1 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- OTOG | c.4120G>A p.G1374S | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PANK3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 75/666 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PARG | c.2680G>T p.E894* | Nonsense Mutation (SNP) | VAF 59/381 reads (15%) | called by muse, mutect2, varscan2
- PARP14 | c.2486A>T p.H829L | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.338); called by muse, mutect2
- PAX5 | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- PAX8 | c.879G>T p.Q293H | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- PCDH11X | c.2258C>A p.A753D | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PCDH15 | c.4606C>A p.P1536T (on ENST00000644397 / NM_001354429.2; = p.P1485T on NM_001142769.3) | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH15 | c.4160G>C p.C1387S | Missense Mutation (SNP) | VAF 116/1129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH7 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- PCDHA3 | c.1677C>A p.N559K | Missense Mutation (SNP) | VAF 44/778 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA6 | c.1714G>C p.G572R | Missense Mutation (SNP) | VAF 87/632 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHA8 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 94/934 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); called by muse, varscan2
- PCDHGA2 | c.1459G>C p.V487L | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PCDHGB6 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCLO | c.14103A>T p.Q4701H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCYOX1L | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PEAR1 | c.1552G>C p.A518P | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PIKFYVE | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 73/843 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PKHD1L1 | c.10147C>G p.R3383G | Missense Mutation (SNP) | VAF 67/544 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLCXD3 | c.769del p.V257Sfs*20 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | called by mutect2, pindel
- PLD2 | c.2735A>C p.E912A | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLEKHH1 | c.1025T>A p.F342Y | Missense Mutation (SNP) | VAF 45/426 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PNLIPRP2 | c.958G>C p.A320P | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLA1 | c.248-2A>T p.X83_splice | Splice Site (SNP) | VAF 15/307 reads (5%) | called by muse, mutect2
- POU3F4 | c.98A>T p.N33I | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2
- POU3F4 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- POU6F2 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PPP1R3F | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF10 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 56/908 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF12 | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 30/368 reads (8%) | called by muse, mutect2
- PRAMEF14 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 43/799 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRAMEF19 | c.1438T>C p.*480Qext*? | Nonstop Mutation (SNP) | VAF 98/772 reads (13%) | called by muse, varscan2
- PRC1 | c.822+1G>T p.X274_splice | Splice Site (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- PRDM6 | c.1142A>T p.Q381L | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PRDM8 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 79/732 reads (11%) | called by muse, mutect2, varscan2
- PRKX | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRUNE2 | c.8849T>A p.L2950* | Nonsense Mutation (SNP) | VAF 38/295 reads (13%) | called by muse, mutect2, varscan2
- PRUNE2 | c.2797G>T p.V933F | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PSMD4 | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRC | c.1549C>A p.R517S | Missense Mutation (SNP) | VAF 205/947 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PZP | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- RADIL | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RAG1 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 138/1445 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2
- RALYL | c.143T>A p.I48K | Missense Mutation (SNP) | VAF 73/535 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAPGEF2 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 54/549 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RASA3 | c.1690T>A p.S564T | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2
- RBMXL3 | c.2878C>T p.H960Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.2558T>A p.V853E | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- RET | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 95/621 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIF1 | c.5707G>C p.A1903P | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- RNF112 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPLP2 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- RRS1 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RSPO2 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 89/561 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RTL1 | c.2258T>C p.L753P | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTL4 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- RUNX1T1 | c.933C>A p.Y311* (on ENST00000265814 / NM_001198628.1; = p.Y284* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2
- RYR2 | c.11115C>A p.D3705E | Missense Mutation (SNP) | VAF 47/521 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RYR2 | c.12473C>A p.T4158N | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SACS | c.5166A>T p.K1722N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- SALL3 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- SCN10A | c.3265G>T p.V1089L | Missense Mutation (SNP) | VAF 30/567 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2
- SEMA3D | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 46/580 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- SEMA6A | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 62/487 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB11 | c.476-1G>T p.X159_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | called by mutect2, varscan2
- SH3KBP1 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK2 | c.1378del p.A460Pfs*97 | Frame Shift Del (DEL) | VAF 50/237 reads (21%) | called by mutect2, pindel, varscan2
- SKAP1 | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 104/843 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC12A5 | c.2051A>C p.E684A (on ENST00000454036 / NM_001134771.2; = p.E661A on NM_020708.5) | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SLC13A5 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC16A1 | c.1225T>A p.L409I | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2
- SLC17A4 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 143/552 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC17A6 | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC27A6 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC29A2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 60/525 reads (11%) | called by muse, mutect2, varscan2
- SLC38A8 | c.1044G>T p.M348I | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, varscan2
- SLC5A2 | c.1847G>C p.G616A | Missense Mutation (SNP) | VAF 95/664 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SLC5A5 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 112/689 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SLC6A11 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 85/709 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A14 | c.434T>A p.I145N | Missense Mutation (SNP) | VAF 42/906 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC7A3 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLIT1 | c.4445C>A p.P1482H | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SLIT2 | c.3209G>T p.G1070V | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMAP2 | c.848-1G>A p.X283_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- SNAP91 | c.1988C>G p.S663* | Nonsense Mutation (SNP) | VAF 52/472 reads (11%) | called by muse, mutect2, varscan2
- SNTG1 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 75/455 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- SORCS1 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SOX18 | c.1061C>A p.P354Q | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- SOX5 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPANXN1 | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- SPATA31A1 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 110/1380 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- SPATA31A3 | c.3382T>A p.L1128M | Missense Mutation (SNP) | VAF 62/1838 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPATA31A7 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 95/1731 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SPEF2 | c.5287G>T p.A1763S | Missense Mutation (SNP) | VAF 91/498 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPON1 | c.2334C>A p.Y778* | Nonsense Mutation (SNP) | VAF 32/425 reads (8%) | called by muse, mutect2
- SPOUT1 | c.36+1G>T p.X12_splice | Splice Site (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- SRSF11 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- STK33 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, mutect2
- STXBP2 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 52/432 reads (12%) | called by muse, mutect2, varscan2
- STXBP5L | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 41/668 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- SUCLG1 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 46/1006 reads (5%) | called by muse, mutect2
- TAF4B | c.2297T>G p.L766* | Nonsense Mutation (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- TAF5L | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2
- TAS2R39 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TBC1D15 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBR1 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBXA2R | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- TCTE1 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM2 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TENM3 | c.403T>G p.W135G | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- TFAP2B | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- THBS2 | c.2918C>A p.T973N | Missense Mutation (SNP) | VAF 63/493 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- TIE1 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- TLR1 | c.1103G>T p.C368F | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TM6SF1 | c.922-1G>C p.X308_splice | Splice Site (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- TMEM132B | c.1889C>A p.T630N | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TMEM132C | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- TMEM178A | c.454T>A p.L152M | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM178B | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMEM202 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 21/457 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2
- TOPORS | c.709A>T p.R237W | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- TP53BP2 | c.1639G>T p.G547* (on ENST00000343537 / NM_001031685.3; = p.G418* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 54/472 reads (11%) | called by muse, mutect2, varscan2
- TPTE | c.1324G>T p.V442F (on ENST00000618007 / NM_199261.4; = p.V424F on NM_199259.4) | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2
- TRAPPC3L | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 25/359 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.276); called by muse, mutect2
- TRBC2 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 30/678 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRHDE | c.2966C>A p.A989D | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- TRIM15 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 109/481 reads (23%) | called by muse, mutect2, varscan2
- TRIM77 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.624); called by muse, varscan2
- TRIR | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPEAR | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- TTC24 | c.1668-1G>C p.X556_splice | Splice Site (SNP) | VAF 18/375 reads (5%) | called by muse, mutect2
- UGT2B10 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 63/507 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- UNC5A | c.2315G>T p.R772M | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UNC79 | c.7351C>T p.L2451F (on ENST00000393151 / NM_001346218.2; = p.L2274F on NM_020818.5) | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- UROC1 | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 23/702 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- USH2A | c.4886-2A>T p.X1629_splice | Splice Site (SNP) | VAF 90/740 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.4658C>A p.P1553H | Missense Mutation (SNP) | VAF 44/607 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- USH2A | c.4627G>T p.G1543C | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- USH2A | c.2110G>T p.G704* | Nonsense Mutation (SNP) | VAF 141/731 reads (19%) | called by muse, mutect2, varscan2
- USH2A | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 72/668 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- USP34 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2
- VAV3 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2
- VIRMA | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- VKORC1L1 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 39/906 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWC2 | c.905G>A p.C302Y | Missense Mutation (SNP) | VAF 40/712 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VWDE | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 78/583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- WDR17 | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 31/473 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR17 | c.2709del p.E904Kfs*59 | Frame Shift Del (DEL) | VAF 25/251 reads (10%) | called by mutect2, pindel, varscan2
- WHAMM | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- WT1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- XIRP2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 48/557 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2
- ZFHX4 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZFHX4 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 50/395 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- ZMAT1 | c.857T>A p.I286N | Missense Mutation (SNP) | VAF 66/524 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- ZNF511 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 51/491 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- ZNF525 | c.594T>A p.N198K | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.287); called by muse, mutect2
- ZNF555 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 89/542 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF615 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 40/546 reads (7%) | called by muse, mutect2
- ZNF669 | c.1337G>C p.C446S | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF831 | c.4720C>A p.P1574T | Missense Mutation (SNP) | VAF 149/763 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF875 | c.-162C>T | Splice Region (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- ZP2 | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZSCAN31 | c.1154G>T p.S385I | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ZSCAN5B | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM33 | c.1125G>T p.A375= | Silent (SNP) | VAF 16/405 reads (4%) | called by muse, mutect2
- ADAMTS4 | c.795G>T p.V265= | Silent (SNP) | VAF 127/497 reads (26%) | called by muse, mutect2, varscan2
- ADCY2 | c.2646C>T p.S882= | Silent (SNP) | VAF 84/376 reads (22%) | catalogued as rs773835529; called by muse, mutect2, varscan2
- ADCY8 | c.2811C>A p.I937= | Silent (SNP) | VAF 96/604 reads (16%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2217A>T p.V739= | Silent (SNP) | VAF 55/492 reads (11%) | catalogued as COSV65423179; called by muse, mutect2, varscan2
- ADGRG4 | c.1983C>T p.D661= | Silent (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.1860G>T p.R620= | Silent (SNP) | VAF 14/352 reads (4%) | catalogued as COSV57045295, COSV57046381; called by muse, mutect2
- AFDN | c.2265A>G p.Q755= | Silent (SNP) | VAF 37/304 reads (12%) | called by muse, mutect2, varscan2
- AK2 | c.303G>T p.L101= (on ENST00000354858; = p.L143= on NM_001625.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/957 reads (13%) | called by muse, mutect2, varscan2
- AKAP4 | c.555C>A p.T185= | Silent (SNP) | VAF 41/695 reads (6%) | called by muse, mutect2
- ALAS2 | c.645C>A p.T215= | Silent (SNP) | VAF 36/443 reads (8%) | catalogued as rs1569547857; called by muse, mutect2
- ANK2 | c.8520C>A p.P2840= | Silent (SNP) | VAF 75/842 reads (9%) | called by muse, mutect2
- ANKRD33 | c.36G>T p.V12= (on ENST00000340970 / NM_001304459.2; = p.V147= on NM_182608.4) | Silent (SNP) | VAF 37/425 reads (9%) | called by muse, mutect2
- ANO4 | c.672A>T p.T224= (on ENST00000392977 / NM_001286615.2; = p.T189= on NM_178826.4) | Silent (SNP) | VAF 36/527 reads (7%) | called by muse, mutect2
- APBB2 | c.816C>A p.P272= | Silent (SNP) | VAF 34/198 reads (17%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.2388G>A p.Q796= | Silent (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- ARHGAP24 | c.354G>A p.K118= | Silent (SNP) | VAF 56/551 reads (10%) | called by muse, mutect2, varscan2
- ATG9B | c.672C>T p.F224= | Silent (SNP) | VAF 24/316 reads (8%) | catalogued as COSV65060140; called by muse, mutect2
- BAHD1 | c.1395C>T p.T465= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- BHLHE22 | c.403C>A p.R135= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- BIRC6 | c.2166G>T p.L722= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- C1orf105 | c.114T>A p.P38= | Silent (SNP) | VAF 48/232 reads (21%) | called by muse, mutect2, varscan2
- C22orf15 | c.105C>A p.P35= | Silent (SNP) | VAF 67/332 reads (20%) | called by muse, mutect2, varscan2
- CACNA1E | c.66C>T p.S22= | Silent (SNP) | VAF 60/266 reads (23%) | called by mutect2, varscan2
- CACNA1E | c.2400G>A p.E800= | Silent (SNP) | VAF 67/292 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.5049C>A p.T1683= | Silent (SNP) | VAF 61/512 reads (12%) | called by muse, mutect2, varscan2
- CAPN1 | c.1359G>T p.V453= | Silent (SNP) | VAF 49/173 reads (28%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.5076T>A p.T1692= | Silent (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- CCDC88C | c.5487G>T p.L1829= | Silent (SNP) | VAF 39/313 reads (12%) | called by muse, mutect2, varscan2
- CCKAR | c.867C>T p.S289= | Silent (SNP) | VAF 64/609 reads (11%) | called by muse, mutect2, varscan2
- CCNL2 | c.1527G>A p.E509= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- CCR2 | c.24G>T p.R8= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- CD7 | c.177G>A p.L59= | Silent (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- CDC25C | c.1225C>T p.L409= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as COSV60399264; called by muse, mutect2
- CDH20 | c.2124C>A p.L708= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as COSV53010168; called by muse, mutect2, varscan2
- CDH23 | c.3489C>T p.P1163= | Silent (SNP) | VAF 76/581 reads (13%) | called by muse, mutect2, varscan2
- CELF5 | c.744C>A p.A248= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- CES2 | c.636C>T p.I212= | Silent (SNP) | VAF 16/578 reads (3%) | catalogued as rs913361346; called by muse, mutect2
- CIT | c.24G>T p.A8= | Silent (SNP) | VAF 32/355 reads (9%) | called by muse, mutect2
- CLMN | c.2889G>T p.P963= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2784G>A p.G928= | Silent (SNP) | VAF 74/948 reads (8%) | catalogued as rs769108523; called by muse, mutect2
- COL12A1 | c.8781G>C p.L2927= | Silent (SNP) | VAF 66/364 reads (18%) | catalogued as rs953982457, COSV59402769; called by mutect2, varscan2
- COL4A4 | c.1650T>G p.P550= | Silent (SNP) | VAF 34/776 reads (4%) | called by muse, mutect2
- CORIN | c.414C>A p.A138= | Silent (SNP) | VAF 32/307 reads (10%) | called by muse, mutect2
- CPA2 | c.378G>T p.L126= | Silent (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- CTCFL | c.1224C>A p.T408= | Silent (SNP) | VAF 98/462 reads (21%) | called by muse, mutect2, varscan2
- CYP39A1 | c.1356G>T p.V452= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs1236930012; called by muse, mutect2, varscan2
- CYP4F8 | c.1209C>G p.T403= | Silent (SNP) | VAF 58/318 reads (18%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.831G>T p.L277= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- DEFA4 | c.15C>A p.A5= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs770823381; called by muse, mutect2, varscan2
- DGKB | c.597C>A p.L199= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- DGKI | c.2586G>T p.P862= | Silent (SNP) | VAF 34/571 reads (6%) | catalogued as rs555376064; called by muse, mutect2
- DKK4 | c.21G>A p.L7= | Silent (SNP) | VAF 79/387 reads (20%) | called by muse, mutect2, varscan2
- DLL3 | c.1383A>T p.G461= | Silent (SNP) | VAF 62/351 reads (18%) | called by muse, mutect2, varscan2
- DNAH10 | c.13269C>T p.F4423= (on ENST00000409039; = p.F4362= on NM_207437.3) | Silent (SNP) | VAF 30/223 reads (13%) | catalogued as COSV53018683; called by muse, mutect2, varscan2
- DOCK2 | c.2595G>C p.L865= | Silent (SNP) | VAF 66/545 reads (12%) | called by muse, mutect2, varscan2
- DSCAML1 | c.345G>C p.A115= (on ENST00000321322; = p.A55= on NM_020693.4) | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- DUSP10 | c.606G>C p.R202= | Silent (SNP) | VAF 84/596 reads (14%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1599C>A p.T533= | Silent (SNP) | VAF 91/347 reads (26%) | catalogued as COSV62568028; called by muse, mutect2, varscan2
- EFL1 | c.2964C>T p.D988= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs747853447; called by muse, mutect2, varscan2
- EMILIN3 | c.975C>A p.G325= | Silent (SNP) | VAF 91/454 reads (20%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2694C>A p.T898= | Silent (SNP) | VAF 36/536 reads (7%) | called by muse, mutect2
- ERV3-1 | c.1479C>T p.G493= | Silent (SNP) | VAF 59/258 reads (23%) | catalogued as rs1042040313; called by muse, mutect2, varscan2
- ETV1 | c.411C>T p.P137= | Silent (SNP) | VAF 40/507 reads (8%) | catalogued as rs759513197, COSV54148561; called by muse, mutect2
- EYS | c.2802T>C p.S934= | Silent (SNP) | VAF 36/324 reads (11%) | called by muse, mutect2, varscan2
- EYS | c.2355C>T p.T785= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as rs924694135; called by muse, mutect2
- FAT4 | c.10176T>A p.T3392= | Silent (SNP) | VAF 45/376 reads (12%) | called by muse, mutect2, varscan2
- FAT4 | c.10443A>T p.S3481= | Silent (SNP) | VAF 65/618 reads (11%) | called by muse, mutect2, varscan2
- FBXO10 | c.2565G>C p.R855= | Silent (SNP) | VAF 27/354 reads (8%) | called by muse, mutect2
- FSTL4 | c.531C>T p.L177= | Silent (SNP) | VAF 34/426 reads (8%) | catalogued as rs148727806, COSV99530867, COSV99532228; called by muse, mutect2
- GAS1 | c.468C>A p.G156= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- GMEB2 | c.879G>C p.L293= | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- GP1BA | c.387C>G p.T129= | Silent (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2
- GPA33 | c.675G>A p.T225= | Silent (SNP) | VAF 84/330 reads (25%) | catalogued as rs374776660, COSV63302573; called by muse, mutect2, varscan2
- GPN1 | c.1014C>T p.S338= | Silent (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- GPR148 | c.333G>T p.L111= | Silent (SNP) | VAF 14/394 reads (4%) | called by muse, mutect2
- GPR158 | c.3582T>C p.S1194= | Silent (SNP) | VAF 59/431 reads (14%) | called by muse, mutect2, varscan2
- GPR25 | c.600G>A p.Q200= | Silent (SNP) | VAF 52/458 reads (11%) | called by muse, varscan2
- GRIA2 | c.2298G>T p.A766= | Silent (SNP) | VAF 33/272 reads (12%) | catalogued as COSV99645796; called by muse, mutect2, varscan2
- GRIK1 | c.2310C>A p.I770= | Silent (SNP) | VAF 38/500 reads (8%) | catalogued as rs144877234, COSV58710259; called by muse, mutect2
- GRM6 | c.2004G>A p.L668= | Silent (SNP) | VAF 40/394 reads (10%) | called by muse, mutect2, varscan2
- HDC | c.996C>A p.P332= | Silent (SNP) | VAF 50/833 reads (6%) | called by muse, mutect2
- HEPH | c.2481G>A p.K827= (on ENST00000343002; = p.K560= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/475 reads (8%) | called by muse, mutect2
- HIP1R | c.2037G>A p.L679= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV53443555; called by muse, mutect2, varscan2
- HRH2 | c.468G>T p.L156= | Silent (SNP) | VAF 59/518 reads (11%) | called by muse, mutect2, varscan2
- HTR1E | c.96C>T p.I32= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- IFNE | c.39G>T p.L13= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2
- IFT140 | c.2238G>A p.G746= | Silent (SNP) | VAF 64/533 reads (12%) | called by muse, mutect2, varscan2
- IGHE | c.1023C>A p.R341= | Silent (SNP) | VAF 46/237 reads (19%) | called by muse, varscan2
- IL1RAP | c.726C>T p.P242= | Silent (SNP) | VAF 119/588 reads (20%) | called by muse, mutect2, varscan2
- INPP5D | c.1965C>A p.A655= (on ENST00000445964 / NM_001017915.3; = p.A654= on NM_005541.5) | Silent (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- INSRR | c.3042G>C p.T1014= | Silent (SNP) | VAF 88/453 reads (19%) | catalogued as COSV63875788; called by muse, mutect2, varscan2
- KCNA6 | c.984C>A p.G328= | Silent (SNP) | VAF 24/355 reads (7%) | catalogued as rs200079703, COSV54974703, COSV54977171, COSV99768734; called by muse, mutect2
- KCNB2 | c.1830C>G p.A610= | Silent (SNP) | VAF 30/366 reads (8%) | catalogued as COSV73053258; called by muse, mutect2
- KCNF1 | c.684G>A p.A228= | Silent (SNP) | VAF 22/484 reads (5%) | catalogued as COSV54462058; called by muse, mutect2
- KCNMB4 | c.481C>T p.L161= | Silent (SNP) | VAF 18/694 reads (3%) | called by muse, mutect2
- KLRG2 | c.501G>T p.P167= | Silent (SNP) | VAF 13/181 reads (7%) | called by muse, mutect2
- KRTAP10-8 | c.189T>C p.P63= | Silent (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- KRTAP4-1 | c.204C>A p.V68= | Silent (SNP) | VAF 112/716 reads (16%) | catalogued as COSV66649864; called by muse, varscan2
- KRTAP6-2 | c.93C>A p.R31= | Silent (SNP) | VAF 27/488 reads (6%) | called by muse, mutect2
- LGALS3BP | c.838C>T p.L280= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- LPAR4 | c.519C>A p.A173= | Silent (SNP) | VAF 25/546 reads (5%) | called by muse, mutect2
- LRP1B | c.3216C>G p.R1072= | Silent (SNP) | VAF 46/535 reads (9%) | called by muse, mutect2
- LRRTM3 | c.795C>T p.I265= | Silent (SNP) | VAF 36/396 reads (9%) | catalogued as COSV63662267, COSV63667855; called by muse, mutect2
- LTBP2 | c.4074C>A p.A1358= | Silent (SNP) | VAF 83/848 reads (10%) | called by muse, mutect2
- MAGEB18 | c.201C>A p.A67= | Silent (SNP) | VAF 50/276 reads (18%) | called by muse, mutect2, varscan2
- MAGEE1 | c.78C>A p.G26= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- MAGEE1 | c.267C>T p.S89= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs782711133, COSV100819563; called by muse, mutect2
- MSI2 | c.825G>T p.G275= | Silent (SNP) | VAF 47/300 reads (16%) | catalogued as COSV52353219; called by muse, mutect2, varscan2
- MUC17 | c.5577C>A p.T1859= | Silent (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- NID1 | c.1602G>A p.K534= | Silent (SNP) | VAF 87/1057 reads (8%) | called by muse, mutect2
- NKX3-1 | c.555C>T p.S185= | Silent (SNP) | VAF 61/433 reads (14%) | called by muse, mutect2, varscan2
- NLRP1 | c.1704C>T p.L568= | Silent (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- NMUR2 | c.204G>T p.L68= | Silent (SNP) | VAF 43/608 reads (7%) | called by muse, mutect2
- NPBWR2 | c.192G>A p.T64= | Silent (SNP) | VAF 24/696 reads (3%) | catalogued as rs375955446, COSV100871111; called by muse, mutect2
- NPR2 | c.1986C>T p.D662= | Silent (SNP) | VAF 118/872 reads (14%) | called by muse, mutect2, varscan2
- OCA2 | c.912C>A p.I304= | Silent (SNP) | VAF 23/784 reads (3%) | called by muse, mutect2
- OCA2 | c.360C>T p.F120= | Silent (SNP) | VAF 38/1108 reads (3%) | called by muse, mutect2
190 further variants in this file (0 protein-altering or splice-affecting, 96 silent, 94 other) are not listed here.
